HCMI case HCM-BROD-0830-C71 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/85f48da8-16cc-4e6f-9f1b-2eaed60f93d8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1958; Vital status: Dead; Days to death: 1,067 days (2.9 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 58.4 years (21,323 days); WHO CNS grade: Grade IV; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 0 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.
2. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: recurrence; Age at diagnosis: 61.2 years (22,359 days); Days to diagnosis: 1,036 days (2.8 years).
   Pathology details: Necrosis present: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Temozolomide; Treatment intent type: Maintenance Therapy; Days to treatment start: 202 days; Days to treatment end: 328 days; Treatment outcome: Progressive Disease.

Follow-up (3 entries)
- Days to follow up: 1,029 days (2.8 years); Karnofsky performance status: 80.
- Days to follow up: 1,067 days (2.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contacts recording only the day: day 1,036, day 1,040.

Molecular and laboratory tests
- IDH1 (IHC): Negative; Amino-acid change: R132H.
- IDH1 / IDH2 (Targeted Sequencing): Negative.
- MGMT methylation: Positive.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 44.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0830-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0830-C71-02A-01-S2-HE: Section location: Bottom; Percent tumor cells: 96; Percent tumor nuclei: 98; Percent normal cells: 0; Percent necrosis: 4; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0830-C71-02A-01-S1-HE: Section location: Top; Percent tumor cells: 98; Percent tumor nuclei: 98; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0830-C71-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0830-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen; Passage count: 10.
